Somatic mutation profile of tumor specimen TCGA-2J-AABP-01A (aliquot TCGA-2J-AABP-01A-11D-A40W-08) from TCGA case TCGA-2J-AABP, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G4; Age at diagnosis: 58.8 years (21,484 days).
Specimen TCGA-2J-AABP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b27de48c-4390-42c7-94b5-a87b9b418b4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AABP-10A (Blood Derived Normal), aliquot TCGA-2J-AABP-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4dd9458-5a40-4535-8ccd-14aa936602fb

The open-access MAF lists 113 somatic variants for this specimen: 88 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 23, Nonsense Mutation 5, RNA 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SNX10 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 156/563 reads (28%) | catalogued as rs587777490, CM130184, COSV100640068; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 188/325 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACE2 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 34/768 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.862); catalogued as COSV99382696; called by muse, mutect2
- ACTL7B | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 58/414 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.104); catalogued as rs761937962, COSV65927502; called by muse, mutect2, varscan2
- ACVR1C | c.1158C>A p.F386L | Missense Mutation (SNP) | VAF 22/503 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV99694573; called by muse, mutect2
- ADAR | c.1723G>T p.A575S | Missense Mutation (SNP) | VAF 63/481 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.985); catalogued as COSV99425830; called by muse, mutect2, varscan2
- APBA2 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs199985120, COSV68792040; called by muse, mutect2
- ARFIP2 | c.874A>C p.K292Q | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99601492; called by muse, mutect2, varscan2
- ARRB2 | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 90/143 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99347011; called by muse, mutect2, varscan2
- ARSA | c.1336G>A p.G446S | Missense Mutation (SNP) | VAF 54/620 reads (9%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV99332357; called by muse, mutect2
- ATP9A | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 238/608 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs758734749, COSV58770824; called by muse, mutect2, varscan2
- CCDC170 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 51/419 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as rs1159721192, COSV53339314, COSV53340316; called by muse, mutect2, varscan2
- CD93 | c.475A>T p.K159* | Nonsense Mutation (SNP) | VAF 30/329 reads (9%) | catalogued as COSV99849106; called by muse, mutect2
- CDH10 | c.61T>A p.S21T | Missense Mutation (SNP) | VAF 47/743 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100051019; called by muse, mutect2
- CLEC12B | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1252207406, COSV100138946; called by muse, mutect2, varscan2
- CMTM8 | c.148G>T p.V50F | Missense Mutation (SNP) | VAF 60/706 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV100282486; called by muse, mutect2
- COL4A4 | c.4677C>G p.I1559M | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100306623, COSV100307265; called by muse, mutect2, varscan2
- CRTAM | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 125/290 reads (43%) | catalogued as rs533016781, COSV99911944; called by muse, mutect2, varscan2
- CSMD1 | c.927C>G p.F309L | Missense Mutation (SNP) | VAF 8/236 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as rs939374561; called by muse, mutect2
- CTAG2 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 56/748 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as rs199533324, COSV99908851; called by muse, mutect2
- CYP11B2 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.624); catalogued as rs371296931, COSV100010932; called by muse, mutect2
- DCAF4L1 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 41/631 reads (6%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60787947; called by muse, mutect2
- DGKB | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 93/635 reads (15%) | catalogued as COSV99338489; called by muse, mutect2, varscan2
- DNAH5 | c.3120C>A p.C1040* | Nonsense Mutation (SNP) | VAF 46/756 reads (6%) | catalogued as COSV99448358; called by muse, mutect2
- DRD1 | c.497C>A p.A166E | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.864); catalogued as COSV101192429; called by muse, mutect2, varscan2
- DYNC1I2 | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55529553; called by muse, mutect2, varscan2
- ECSIT | c.790A>G p.I264V | Missense Mutation (SNP) | VAF 50/393 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.497); catalogued as rs770450369, COSV99368972; called by muse, mutect2, varscan2
- EXOC6B | c.2297C>T p.T766I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99723693; called by muse, mutect2
- FAM13B | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 42/351 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV99221238; called by muse, mutect2, varscan2
- FLG2 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 94/173 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.295); catalogued as COSV101165785; called by muse, mutect2, varscan2
- GAS2 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 115/271 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs767695285, COSV99534956; called by muse, mutect2, varscan2
- GLIS3 | c.2057C>G p.S686C | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.635); catalogued as rs1563754775, COSV100173765, COSV60925585; called by muse, mutect2
- HSPA12B | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.178); catalogued as rs867494918, COSV99653944; called by muse, mutect2, varscan2
- IL27RA | c.329C>A p.A110E | Missense Mutation (SNP) | VAF 43/379 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99652088; called by muse, mutect2, varscan2
- IRAG2 | c.2908G>A p.V970M (on ENST00000636465; = p.V15M on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/514 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs143325687, COSV63140072; called by muse, varscan2
- ITCH | c.1408A>G p.R470G (on ENST00000262650 / NM_001257137.3; = p.R429G on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99392307; called by muse, mutect2
- KLHL14 | c.932A>T p.Q311L | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100808880; called by muse, mutect2
- LILRB4 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 146/386 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1375911983, COSV54409868, COSV99553868; called by muse, mutect2, varscan2
- LPL | c.249+2T>C p.X83_splice | Splice Site (SNP) | VAF 14/238 reads (6%) | catalogued as rs1417559091, COSV100255508; called by muse, mutect2
- LRP1B | c.7501A>C p.N2501H | Missense Mutation (SNP) | VAF 47/432 reads (11%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.989); catalogued as COSV101255406; called by muse, mutect2, varscan2
- MUC16 | c.6373G>T p.A2125S | Missense Mutation (SNP) | VAF 204/611 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV101199405; called by muse, mutect2, varscan2
- MYH14 | c.3386C>A p.S1129Y | Missense Mutation (SNP) | VAF 89/165 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99222416; called by muse, mutect2, varscan2
- MYO1E | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 44/569 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs765938827, COSV99895195; called by muse, mutect2
- NFATC2 | c.1742A>G p.E581G | Missense Mutation (SNP) | VAF 116/1205 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101043957; called by muse, mutect2
- NKG7 | c.489A>T p.E163D | Missense Mutation (SNP) | VAF 104/1482 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV99389857; called by muse, mutect2
- NNT | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 106/2718 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759627384, COSV99238736; called by muse, mutect2
- NRCAM | c.641A>G p.E214G (on ENST00000379028 / NM_001371124.1; = p.E208G on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/560 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV100694569; called by muse, mutect2, varscan2
- NRXN1 | c.2707A>G p.I903V | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs1375757334, COSV58450461; called by muse, mutect2
- OR10H2 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 15/280 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as rs1350085212, COSV100008724; called by muse, mutect2
- OR10R2 | c.277T>C p.Y93H | Missense Mutation (SNP) | VAF 78/739 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100936781; called by muse, mutect2, varscan2
- OR51B5 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV56176093; called by muse, mutect2, varscan2
- OR8H3 | c.241A>G p.K81E | Missense Mutation (SNP) | VAF 140/1458 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs749136845, COSV100538881; called by muse, varscan2
- PDE1B | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs200096201; called by muse, mutect2
- PDLIM5 | c.856C>T p.L286F | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58750595; called by muse, mutect2
- PEG3 | c.1262A>G p.E421G | Missense Mutation (SNP) | VAF 76/737 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as COSV99688449; called by muse, mutect2, varscan2
- PPP1R13B | c.335A>G p.E112G | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99158383; called by muse, mutect2, varscan2
- PRDM9 | c.1157A>G p.E386G | Missense Mutation (SNP) | VAF 44/879 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV99690256; called by muse, mutect2
- PRPF6 | c.1723A>T p.S575C | Missense Mutation (SNP) | VAF 136/430 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99411844; called by muse, mutect2, varscan2
- PTPRT | c.652A>G p.K218E | Missense Mutation (SNP) | VAF 555/1634 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV100626605; called by muse, mutect2, varscan2
- RABGGTB | c.79A>G p.I27V | Missense Mutation (SNP) | VAF 292/541 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs1331764043, COSV100175021; called by muse, mutect2, varscan2
- RANBP3 | c.1015G>A p.E339K (on ENST00000340578 / NM_007322.3; = p.E334K on NM_003624.3) | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as rs772017572, COSV99222257; called by muse, mutect2, varscan2
- RNF44 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV99221867; called by muse, mutect2, varscan2
- SCN2A | c.2573T>C p.F858S | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99331093; called by muse, mutect2, varscan2
- SDE2 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 38/355 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV99682612; called by muse, mutect2
- SIGIRR | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 245/1049 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100229966; called by muse, mutect2, varscan2
- SLC17A7 | c.674C>G p.A225G | Missense Mutation (SNP) | VAF 93/195 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as COSV99676772; called by muse, mutect2, varscan2
- SLC26A9 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs755293789, COSV100536275; called by muse, mutect2
- SLC35G5 | c.1007T>A p.V336E | Missense Mutation (SNP) | VAF 83/292 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99644188; called by muse, mutect2
- SOX6 | c.1483A>G p.T495A (on ENST00000528429 / NM_001145819.2; = p.T468A on NM_017508.3) | Missense Mutation (SNP) | VAF 16/317 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs951523431, COSV100321871; called by muse, mutect2
- SPRR2E | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 95/988 reads (10%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.26); catalogued as COSV100907429; called by muse, mutect2
- STAP1 | c.147G>T p.L49F | Missense Mutation (SNP) | VAF 80/1082 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99609351; called by muse, mutect2
- STAT2 | c.1686G>C p.E562D | Missense Mutation (SNP) | VAF 235/503 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100028803; called by muse, mutect2, varscan2
- TBC1D9B | c.2593C>T p.R865W | Missense Mutation (SNP) | VAF 169/455 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as rs775027882, COSV100783497; called by muse, mutect2, varscan2
- TENM1 | c.8161G>A p.E2721K | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs765774675, COSV64424593; called by muse, mutect2
- TIGD5 | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs867839837, COSV99643409; called by muse, mutect2
- TIGD5 | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99643410; called by muse, mutect2, varscan2
- TIGD6 | c.704C>G p.P235R | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99697820; called by muse, mutect2, varscan2
- TINAG | c.1352T>G p.L451R | Missense Mutation (SNP) | VAF 58/656 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99449280; called by muse, mutect2
- TLN2 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 37/361 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs763045450, COSV100168719; called by muse, mutect2, varscan2
- TRPV4 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868185064, CM114156, COSV99924602; called by muse, mutect2, varscan2
- TSPAN5 | c.469T>A p.F157I | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.1); catalogued as COSV99995434; called by muse, mutect2
- TTLL10 | c.305A>T p.E102V (on ENST00000379289 / NM_001130045.2; = p.E29V on NM_153254.3) | Missense Mutation (SNP) | VAF 66/101 reads (65%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.055); catalogued as COSV101016622; called by muse, mutect2, varscan2
- UBQLNL | c.1087A>G p.I363V | Missense Mutation (SNP) | VAF 73/505 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100974241; called by muse, mutect2, varscan2
- VAV1 | c.2363A>T p.K788I | Missense Mutation (SNP) | VAF 60/729 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV100408919; called by muse, mutect2
- ZC3H7B | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100687255; called by muse, mutect2
- ZNF17 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 28/516 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs376983619; called by muse, mutect2
- ZNF777 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 103/1484 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs201615239, COSV56098499; called by muse, mutect2
- RIMS2 | c.3002T>A p.F1001Y (on ENST00000666250 / NM_001348490.2; = p.F809Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/502 reads (3%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2
- ABCA12 | c.4182G>A p.L1394= (on ENST00000272895 / NM_173076.3; = p.L1076= on NM_015657.3) | Silent (SNP) | VAF 65/180 reads (36%) | catalogued as COSV55963985, COSV99789450; called by muse, mutect2, varscan2
- ABHD3 | c.312G>A p.P104= | Silent (SNP) | VAF 254/473 reads (54%) | catalogued as rs768868084, COSV100004308; called by muse, mutect2, varscan2
- ADCY2 | c.1797G>A p.A599= | Silent (SNP) | VAF 110/410 reads (27%) | catalogued as rs778398128, COSV57859762; called by muse, mutect2, varscan2
- ATP4A | c.2697G>A p.A899= | Silent (SNP) | VAF 44/766 reads (6%) | catalogued as rs200535073, COSV52865580; called by muse, mutect2
- CD5L | c.594A>G p.R198= | Silent (SNP) | VAF 28/305 reads (9%) | catalogued as COSV100941032; called by muse, mutect2
- CDH18 | c.321G>A p.T107= | Silent (SNP) | VAF 37/590 reads (6%) | catalogued as rs370029789; called by muse, mutect2
- CFAP61 | c.3231A>G p.V1077= | Silent (SNP) | VAF 31/478 reads (6%) | catalogued as COSV99844363; called by muse, mutect2
- FDXR | c.1140C>T p.I380= (on ENST00000293195 / NM_024417.5; = p.I386= on NM_004110.6) | Silent (SNP) | VAF 75/779 reads (10%) | catalogued as rs765096765, COSV99500855; called by muse, mutect2
- FIG4 | c.2598A>C p.P866= | Silent (SNP) | VAF 70/698 reads (10%) | catalogued as COSV100019515; called by muse, mutect2, varscan2
- HIVEP1 | c.4725T>C p.S1575= | Silent (SNP) | VAF 37/600 reads (6%) | catalogued as COSV101045058; called by muse, mutect2
- HOXA10 | c.72C>T p.P24= | Silent (SNP) | VAF 172/499 reads (34%) | catalogued as COSV52227807; called by muse, mutect2, varscan2
- IL36G | c.384C>A p.S128= | Silent (SNP) | VAF 350/611 reads (57%) | catalogued as COSV99381141; called by muse, mutect2, varscan2
- KRT2 | c.312T>C p.G104= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs75253159, COSV59008973, COSV59009587, COSV59009958; called by muse, varscan2
- MNS1 | c.918A>G p.L306= | Silent (SNP) | VAF 22/316 reads (7%) | catalogued as COSV99549512; called by muse, mutect2
- MYL3 | c.237C>A p.V79= | Silent (SNP) | VAF 56/475 reads (12%) | catalogued as COSV52767896, COSV99439442; called by muse, mutect2, varscan2
- NEK11 | c.975C>T p.I325= | Silent (SNP) | VAF 122/1104 reads (11%) | catalogued as COSV100797683; called by muse, mutect2, varscan2
- OR4N5 | c.558G>A p.K186= | Silent (SNP) | VAF 274/453 reads (60%) | catalogued as COSV100374076; called by muse, mutect2, varscan2
- PCDHA3 | c.1824G>A p.S608= | Silent (SNP) | VAF 141/447 reads (32%) | catalogued as rs781966718, COSV63539171; called by muse, mutect2, varscan2
- POTEE | c.222G>A p.G74= | Silent (SNP) | VAF 52/1070 reads (5%) | catalogued as rs761059665, COSV100387608; called by muse, mutect2
- PRPF38B | c.1414C>A p.R472= | Silent (SNP) | VAF 46/546 reads (8%) | catalogued as COSV100898247, COSV64223681; called by muse, mutect2
- RRP8 | c.645C>T p.A215= | Silent (SNP) | VAF 21/240 reads (9%) | catalogued as rs778615122, COSV99601870; called by muse, mutect2
- SLC44A4 | c.249G>A p.K83= | Silent (SNP) | VAF 108/410 reads (26%) | catalogued as COSV99998859; called by muse, mutect2, varscan2
- STXBP6 | c.405G>A p.T135= | Silent (SNP) | VAF 30/350 reads (9%) | catalogued as rs373624807; called by muse, mutect2
- AC073310.1 | n.717A>T | RNA (SNP) | VAF 152/734 reads (21%) | called by muse, mutect2, varscan2
- DENND1A | c.1577+1569G>A | Intron (SNP) | VAF 48/441 reads (11%) | catalogued as COSV101011036; called by muse, mutect2, varscan2
